CPTAC case C3N-00299 — Lip — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Lip. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0b5c15c0-6481-4906-b586-8ffb394befd1

Demographics
Sex at birth: male; Race: white; Year of birth: 1962; Vital status: Dead; Days to death: 231 days; Year of death: 2017; Country of birth: Poland.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lip, NOS; Site of resection or biopsy: Lip, NOS; Age at diagnosis: 54.4 years (19,881 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G2; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 231 days; Days to last follow up: -20 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.1 cm (a second GDC size field records 3 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 8; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: No; Vascular invasion present: No.

Follow-up (1 entry)
- Days to follow up: -20 days; Disease response: Tumor Free.

Other clinical attributes
- Weight: 64 kg; Height: 176 cm; BMI: 20.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00299-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 0.206 mg.
- Sample C3N-00299-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lip; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -20 days; Initial weight: 381 mg; Time between excision and freezing: 5 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00299-22: Section location: Lip; Percent tumor nuclei: 85; Percent necrosis: 10.
- Sample C3N-00299-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 0.129 mg.
- Sample C3N-00299-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 0.297 mg.
- Sample C3N-00299-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -20 days; Method of sample procurement: Blood Draw.
